Gene-level copy-number profile of tumor specimen TCGA-D8-A141-01A from TCGA case TCGA-D8-A141, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.0 years (14,626 days).
Specimen TCGA-D8-A141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b96324a1-55fb-4b3a-b813-0305e6bd31c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A141-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ce34361-680b-4f57-a821-9c8ae7192ee3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,186; copy number 2: 43,711; copy number 3: 12,198; copy number 4: 121; copy number 5: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A141-01A-11D-A111-01): tumor purity 0.28, ploidy 2.24, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,604 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,186. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
